Somatic mutation profile of tumor specimen TCGA-DQ-5629-01A (aliquot TCGA-DQ-5629-01A-01D-1870-08) from TCGA case TCGA-DQ-5629, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 64.5 years (23,550 days).
Specimen TCGA-DQ-5629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd057405-1e63-43b1-9fda-61870e522812.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-5629-10A (Blood Derived Normal), aliquot TCGA-DQ-5629-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e815c319-03dd-4a16-828f-0309fa024e9a

The open-access MAF lists 369 somatic variants for this specimen: 271 protein-altering or splice-affecting, 86 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 86, Nonsense Mutation 24, Intron 7, Frame Shift Del 6, Splice Site 6, Frame Shift Ins 5, RNA 4, Splice Region 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457+1G>T p.X153_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | hotspot (GDC flag); catalogued as CS041518, CS941435, COSV58685123, COSV58690553, COSV58696311; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 25/42 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11905C>T p.Q3969* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as rs1405531060, COSV101447290, COSV71296238; called by muse, mutect2, varscan2
- ACAN | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100718755; called by muse, mutect2
- ACSM4 | c.186del p.W62Cfs*19 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as COSV101257306; called by mutect2, pindel, varscan2
- ACSM5 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100089233; called by muse, mutect2, varscan2
- ADAMTS16 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV99942098; called by muse, mutect2, varscan2
- ADAMTS20 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239847; called by muse, mutect2, varscan2
- ADCY2 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603445; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100416680; called by muse, mutect2, varscan2
- ADGRB3 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as COSV101001309; called by muse, mutect2, varscan2
- ADGRL4 | c.748T>A p.S250T | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.076); catalogued as COSV100876283; called by muse, mutect2, varscan2
- AGTR1 | c.388A>T p.I130F | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837090; called by muse, mutect2, varscan2
- AL162417.1 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100923162; called by muse, mutect2, varscan2
- ALMS1 | c.9394C>T p.L3132F | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV100043148; called by muse, mutect2, varscan2
- AMZ1 | c.1328T>C p.F443S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100406520; called by muse, mutect2, varscan2
- ANAPC1 | c.4994A>T p.Q1665L | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100594938; called by muse, mutect2, varscan2
- ANK2 | c.4630G>C p.E1544Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1289663490, COSV100002966; called by muse, mutect2, varscan2
- ANO3 | c.481A>T p.K161* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99884236; called by muse, mutect2, varscan2
- ARHGAP30 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1233696220, COSV100919988; called by muse, mutect2, varscan2
- ARMH4 | c.1786G>T p.V596F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV99958619; called by muse, mutect2, varscan2
- ASCL1 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.654); catalogued as COSV99901908, COSV99902102; called by muse, mutect2
- ATRNL1 | c.1799C>A p.S600Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100746572, COSV61804531; called by muse, mutect2, varscan2
- ATRX | c.2539T>A p.F847I | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as COSV100971180; called by muse, mutect2, varscan2
- AURKC | c.397C>G p.Q133E (on ENST00000302804 / NM_001015878.2; = p.Q99E on NM_003160.3) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100248923; called by muse, mutect2, varscan2
- BAZ1A | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100701187; called by muse, varscan2
- BICC1 | c.1976C>A p.T659K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV99570753; called by muse, mutect2, varscan2
- C10orf71 | c.612C>A p.N204K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100110426; called by muse, mutect2, varscan2
- C16orf71 | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs767807614, COSV54789348, COSV99556451; called by muse, mutect2, varscan2
- C3orf33 | c.250C>T p.R84C (on ENST00000340171 / NM_001308229.2; = p.R41C on NM_173657.2) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as rs369831735; called by muse, mutect2, varscan2
- C9orf152 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs138966973; called by muse, mutect2, varscan2
- CADM2 | c.740C>A p.T247N (on ENST00000407528 / NM_001167674.2; = p.T249N on NM_153184.4) | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.239); catalogued as rs1559752265, COSV101057850; called by muse, mutect2, varscan2
- CAPN6 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136963; called by muse, mutect2, varscan2
- CCDC181 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100890357; called by muse, mutect2, varscan2
- CCDC25 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.334); catalogued as COSV100738304; called by muse, mutect2, varscan2
- CCDC88C | c.5407C>T p.R1803W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1195901294, COSV100485012; called by muse, mutect2
- CD1E | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV100937034; called by muse, mutect2, varscan2
- CD34 | c.808-1G>C p.X270_splice | Splice Site (SNP) | VAF 66/197 reads (34%) | catalogued as COSV100178530; called by muse, mutect2, varscan2
- CEMIP | c.4002C>G p.I1334M | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99587019; called by muse, mutect2, varscan2
- CHRNA6 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV52379058, COSV99373095, COSV99373303; called by muse, mutect2, varscan2
- CNOT1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as COSV100409726; called by muse, mutect2, varscan2
- CNOT1 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100409728; called by muse, mutect2, varscan2
- CNTNAP2 | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100668689; called by muse, mutect2, varscan2
- CNTNAP2 | c.1773C>A p.H591Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100668691; called by muse, mutect2, varscan2
- COL11A1 | c.2528C>A p.P843Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100617552; called by muse, mutect2, varscan2
- COL11A1 | c.2527C>A p.P843T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100617555; called by muse, mutect2, varscan2
- COL11A2 | c.1972-2A>T p.X658_splice (on ENST00000341947 / NM_080680.3; = p.X551_splice on NM_080679.2) | Splice Site (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100554311, COSV100554606; called by muse, mutect2, varscan2
- COL12A1 | c.8577G>A p.P2859= | Splice Region (SNP) | VAF 22/78 reads (28%) | catalogued as COSV59392927, COSV59397976; called by muse, mutect2, varscan2
- COL21A1 | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55181261, COSV99779484; called by muse, mutect2, varscan2
- COL25A1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101212637; called by muse, mutect2, varscan2
- COP1 | c.1449G>C p.K483N | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100443634, COSV58172115; called by muse, mutect2, varscan2
- CPAMD8 | c.3046C>A p.R1016S (on ENST00000651564; = p.R969S on NM_015692.5) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as COSV101488547; called by muse, mutect2, varscan2
- CTNND2 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100479150; called by muse, mutect2, varscan2
- CUTC | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100976171; called by muse, mutect2, varscan2
- DAAM2 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226394; called by muse, mutect2, varscan2
- DCC | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100501698; called by muse, mutect2, varscan2
- DDX23 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.309); catalogued as COSV100339675; called by muse, mutect2, varscan2
- DDX60 | c.5116T>G p.W1706G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV101190559; called by muse, mutect2, varscan2
- DDX60L | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99488001; called by muse, mutect2, varscan2
- DEFB118 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1257514494, COSV53620837, COSV99489277; called by muse, mutect2, varscan2
- DENND4A | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101475391; called by muse, mutect2, varscan2
- DIAPH3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99934000; called by muse, varscan2
- DLK1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV100375335; called by muse, mutect2, varscan2
- DMD | c.5776C>A p.L1926M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100821286; called by muse, mutect2
- DMXL1 | c.3705G>C p.M1235I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100224480; called by muse, mutect2, varscan2
- DNAH7 | c.655A>T p.R219W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100416351; called by muse, mutect2, varscan2
- DOCK3 | c.5135A>T p.H1712L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.015); catalogued as rs770986430, COSV99813731; called by muse, varscan2
- DOK5 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV99374384; called by muse, mutect2, varscan2
- DSG1 | c.3103G>T p.A1035S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1357568445, COSV99936271; called by muse, mutect2
- DST | c.19723C>T p.R6575* (on ENST00000361203 / NM_001374722.1; = p.R4272* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV55012109; called by muse, mutect2, varscan2
- ECH1 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV99669640; called by muse, mutect2, varscan2
- ENHO | c.79T>C p.W27R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV99646996; called by muse, mutect2
- EPM2AIP1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as COSV51620433, COSV99212549; called by muse, mutect2, varscan2
- EPRS1 | c.3206A>T p.K1069M | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100859426; called by muse, mutect2, varscan2
- ERBB4 | c.2060G>T p.R687I | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53517166; called by muse, mutect2, varscan2
- EVA1A | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1321814490, COSV99285749; called by muse, mutect2, varscan2
- F5 | c.4797-2A>G p.X1599_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100889182; called by muse, mutect2, varscan2
- FAM13C | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.82); catalogued as COSV99514272; called by muse, mutect2, varscan2
- FAM181A | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV99967940; called by muse, mutect2, varscan2
- FAM227B | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | catalogued as COSV100175362; called by muse, mutect2, varscan2
- FAM227B | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as rs1352293671, COSV100175364; called by muse, mutect2, varscan2
- FANCI | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV100168305; called by muse, mutect2, varscan2
- FBN1 | c.3836T>C p.V1279A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV57319943; called by muse, mutect2, varscan2
- FCHO1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1232836719, COSV99406282; called by muse, mutect2, varscan2
- FLT4 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV56097667; called by muse, mutect2, varscan2
- FMN2 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100146418; called by muse, mutect2, varscan2
- FRYL | c.8328G>C p.K2776N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99977554; called by muse, mutect2, varscan2
- FUT10 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs139365562, COSV100161616; called by muse, mutect2, varscan2
- GABRA5 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100165493; called by muse, mutect2, varscan2
- GABRG2 | c.1184C>A p.T395N (on ENST00000361925 / NM_001375343.1; = p.T355N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100729777; called by muse, mutect2, varscan2
- GAK | c.3470G>T p.G1157V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100033870; called by muse, mutect2, varscan2
- GFRAL | c.877T>A p.C293S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768596947, COSV100475570; called by muse, mutect2, varscan2
- GHSR | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV99577078; called by muse, mutect2, varscan2
- GK | c.1636A>T p.M546L (on ENST00000427190 / NM_001205019.2; = p.M540L on NM_001128127.2) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100970942; called by muse, mutect2, varscan2
- GLYATL2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV99780463; called by muse, mutect2, varscan2
- GPR37 | c.1069A>T p.I357L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV100391036; called by muse, mutect2, varscan2
- GRM1 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV99267685; called by muse, mutect2, varscan2
- GRM8 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100284653, COSV58827041; called by muse, mutect2, varscan2
- GUCY1B1 | c.938T>A p.L313* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100025761; called by mutect2, varscan2
- GYS1 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99620954; called by muse, mutect2, varscan2
- HMCN1 | c.2263G>T p.G755* | Nonsense Mutation (SNP) | VAF 90/298 reads (30%) | catalogued as COSV99632586; called by muse, mutect2, varscan2
- HPS4 | c.964A>G p.R322G | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs1040644043, COSV100404540; called by muse, mutect2, varscan2
- HS3ST5 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451138; called by muse, mutect2, varscan2
- IFT88 | c.1537G>A p.A513T (on ENST00000319980 / NM_001318493.2; = p.A504T on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs551160953, COSV60674400; called by muse, mutect2, varscan2
- IGKV1D-8 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs374084493; called by muse, mutect2, varscan2
- IMPA2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as COSV99302679; called by muse, mutect2, varscan2
- INPP4B | c.1835A>C p.Y612S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV99525643; called by muse, mutect2, varscan2
- IRGQ | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100338221; called by muse, mutect2, varscan2
- KALRN | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0.247); catalogued as rs1181397779, COSV99565973; called by muse, mutect2, varscan2
- KATNIP | c.2570C>G p.S857* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99851617; called by muse, mutect2, varscan2
- KCNH7 | c.785G>T p.R262I | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs752721502, COSV100036890, COSV59805107; called by muse, mutect2, varscan2
- KCNH7 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753793201, COSV100036895; called by muse, mutect2, varscan2
- KCNK10 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100068885; called by muse, mutect2, varscan2
- KCNK5 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100851903; called by muse, mutect2, varscan2
- KIAA1755 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV99642384; called by muse, mutect2, varscan2
- KIF2B | c.1973A>T p.K658I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99275816; called by muse, mutect2, varscan2
- KIR3DL2 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 86/468 reads (18%) | catalogued as COSV99552232; called by muse, mutect2, varscan2
- KLHL1 | c.1766C>A p.A589D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100917747; called by muse, mutect2, varscan2
- KRT72 | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99537393; called by muse, mutect2, varscan2
- LAMP3 | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | catalogued as COSV99660668; called by muse, mutect2, varscan2
- LCP1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.589); catalogued as rs759151052, COSV100549909, COSV100549989; called by muse, mutect2, varscan2
- LGR5 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs758253482, COSV99878192; called by muse, mutect2, varscan2
- LILRA2 | c.1167C>A p.H389Q | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); catalogued as COSV99253688; called by muse, varscan2
- LINGO2 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV100430887; called by muse, mutect2, varscan2
- LRFN5 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV99984734; called by muse, mutect2, varscan2
- LRRC37B | c.1949G>T p.W650L | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100496397; called by muse, mutect2, varscan2
- LRRCC1 | c.2026A>T p.I676F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100835521; called by muse, mutect2, varscan2
- MAB21L2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100462331; called by muse, mutect2, varscan2
- MAGEL2 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV58569429; called by muse, mutect2, varscan2
- MATR3 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100735271; called by muse, mutect2, varscan2
- MDGA2 | c.2234G>A p.R745K (on ENST00000399232 / NM_001113498.2; = p.R447K on NM_182830.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100637646; called by muse, mutect2, varscan2
- MICAL3 | c.5786G>T p.R1929L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755308125, COSV99349587; called by muse, mutect2, varscan2
- MIOS | c.2354G>A p.C785Y | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100402882; called by muse, mutect2, varscan2
- MLXIPL | c.2036T>G p.L679R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515455; called by muse, mutect2, varscan2
- MME | c.1187A>T p.K396M | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100852464; called by muse, mutect2
- MOGS | c.449T>G p.F150C | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV99281078; called by muse, mutect2, varscan2
- MOS | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.869); catalogued as COSV100322663, COSV100322940; called by muse, mutect2, varscan2
- MPP5 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | catalogued as COSV99907269; called by muse, mutect2, varscan2
- MPP5 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99907271; called by muse, mutect2, varscan2
- MTCH2 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100207055, COSV56767320; called by muse, mutect2, varscan2
- MYH10 | c.4201G>A p.A1401T | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs201117056; called by muse, mutect2, varscan2
- MYO18A | c.5954C>A p.S1985Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100572469, COSV62864672; called by muse, mutect2, varscan2
- MYT1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100115099, COSV60500770; called by muse, mutect2, varscan2
- NEDD1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99901177; called by muse, mutect2, varscan2
- NEUROD6 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51770230; called by muse, mutect2, varscan2
- NFATC2IP | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100297620, COSV57909690; called by muse, mutect2, varscan2
- NID2 | c.3044C>A p.P1015H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99356940; called by muse, mutect2, varscan2
- NID2 | c.1474C>G p.H492D | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV99356941; called by muse, mutect2, varscan2
- NINL | c.3022G>T p.G1008W | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99625773; called by muse, mutect2, varscan2
- NLRP8 | c.2085A>C p.L695F | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV99405653; called by muse, mutect2, varscan2
- NLRX1 | c.1991A>T p.K664M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV99424590; called by muse, mutect2, varscan2
- NOD1 | c.2681T>C p.V894A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99768308; called by muse, mutect2, varscan2
- NPAP1 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.953); catalogued as COSV100275738; called by muse, mutect2, varscan2
- NPM1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV99743836; called by muse, mutect2, varscan2
- NRAP | c.1537C>T p.R513C (on ENST00000359988 / NM_001322945.2; = p.R478C on NM_006175.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs183719002, COSV100748522; called by muse, mutect2, varscan2
- NRXN3 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750343246, COSV59751358; called by muse, mutect2, varscan2
- NRXN3 | c.1908G>T p.K636N (on ENST00000335750 / NM_001330195.2; = p.K263N on NM_004796.6) | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100206372; called by muse, mutect2, varscan2
- OPRL1 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402183; called by muse, mutect2, varscan2
- OR11H6 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100209902; called by muse, mutect2
- OR2A12 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101283183; called by muse, mutect2, varscan2
- OR6C76 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV100094211; called by muse, mutect2, varscan2
- OR6F1 | c.151A>C p.T51P | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100129341; called by muse, mutect2, varscan2
- OR8B3 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100660424; called by muse, mutect2, varscan2
- OR8H2 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV57944435, COSV57946162; called by muse, mutect2, varscan2
- PAK5 | c.1744-1G>T p.X582_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100781205, COSV100781552; called by muse, mutect2, varscan2
- PCDH11X | c.614A>T p.K205M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100013438; called by muse, mutect2, varscan2
- PCDHGB4 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99542639; called by mutect2, varscan2
- PCLO | c.483C>G p.N161K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100434867; called by muse, mutect2, varscan2
- PEX11A | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99175554; called by muse, mutect2, varscan2
- PIWIL1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99806692; called by muse, mutect2, varscan2
- PLCH1 | c.3130G>T p.V1044L (on ENST00000340059 / NM_001130960.2; = p.V1036L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs1213692494, COSV100397592; called by muse, mutect2, varscan2
- PLEKHA6 | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV99692449; called by muse, mutect2, varscan2
- PLEKHG1 | c.2942G>T p.R981L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100651775; called by muse, mutect2, varscan2
- PLOD1 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99538677; called by muse, varscan2
- PLXNA1 | c.3938A>T p.D1313V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99303676; called by muse, mutect2, varscan2
- POU4F2 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99850692; called by muse, mutect2, varscan2
- POU4F3 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100047156; called by muse, mutect2, varscan2
- PRX | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as COSV99397877; called by muse, mutect2, varscan2
- PTPN7 | c.817G>A p.E273K (on ENST00000495688; = p.E312K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV100459992; called by muse, mutect2, varscan2
- RAD21 | c.1084A>T p.M362L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.558); catalogued as COSV52056063; called by muse, mutect2, varscan2
- RAD23A | c.730A>T p.M244L | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV100330897; called by muse, mutect2, varscan2
- RARS2 | c.1041T>A p.D347E | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs1554176945, COSV101057401; called by muse, mutect2, varscan2
- RDH12 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99961890; called by muse, mutect2, varscan2
- REPS1 | c.2069G>A p.S690N (on ENST00000450536 / NM_001286611.2; = p.S689N on NM_031922.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99238889; called by muse, mutect2, varscan2
- RFPL4B | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101480712; called by muse, mutect2, varscan2
- RGS6 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100666659; called by muse, mutect2, varscan2
- RGS7 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs780215301, COSV100469375; called by muse, mutect2, varscan2
- RGS7 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV58559274; called by muse, mutect2, varscan2
- RIPOR3 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.833); catalogued as COSV99246831, COSV99247406; called by muse, mutect2, varscan2
- RNASE3 | c.371del p.T124Sfs*12 | Frame Shift Del (DEL) | VAF 49/104 reads (47%) | catalogued as CM025442, COSV58959715; called by mutect2, pindel, varscan2
- ROBO1 | c.2675A>T p.D892V | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101458996, COSV101459060; called by muse, mutect2, varscan2
- RPS6KA2 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV101551614; called by muse, mutect2, varscan2
- RSL1D1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100852004; called by muse, mutect2, varscan2
- RTCA | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99560026; called by muse, mutect2
- SAMD9 | c.2557G>A p.V853I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs534758372, COSV101180317, COSV66078012; called by muse, mutect2, varscan2
- SAV1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100220837; called by muse, mutect2, varscan2
- SEL1L2 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99533570; called by muse, varscan2
- SEL1L2 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as COSV99533571; called by muse, varscan2
- SIN3B | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99931899; called by muse, mutect2, varscan2
- SLC17A3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100399312; called by muse, mutect2, varscan2
- SLC22A12 | c.338C>G p.T113R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV100327755, COSV60574554; called by muse, mutect2, varscan2
- SLC22A16 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV57928547; called by muse, mutect2, varscan2
- SLC24A5 | c.1279G>T p.G427* | Nonsense Mutation (SNP) | VAF 54/124 reads (44%) | catalogued as COSV51046300; called by muse, mutect2, varscan2
- SLC39A6 | c.2143A>T p.S715C | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99309788; called by muse, mutect2, varscan2
- SLCO1C1 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV99859577; called by muse, mutect2, varscan2
- SNRNP200 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100107865; called by muse, mutect2, varscan2
- SNX27 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1298310803, COSV64327005; called by muse, mutect2, varscan2
- SOGA1 | c.3613G>T p.G1205W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV99414577, COSV99415405; called by muse, mutect2, varscan2
- SPATA2 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV99192891; called by muse, mutect2, varscan2
- SPHKAP | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.78); PolyPhen benign (0.265); catalogued as COSV100764287, COSV60883865; called by muse, mutect2, varscan2
- SPTA1 | c.1489-1G>T p.X497_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100935251; called by muse, mutect2, varscan2
- ST8SIA6 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.417); catalogued as COSV66461576; called by muse, mutect2, varscan2
- STK32C | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100063034; called by muse, mutect2
- SYNE1 | c.1849C>A p.R617S (on ENST00000367255 / NM_182961.4; = p.R624S on NM_033071.3) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV54904111, COSV99572733; called by muse, mutect2, varscan2
- TAF1L | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758406437, COSV99645076; called by muse, mutect2, varscan2
- TAF4 | c.1813A>T p.K605* | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as COSV99434658; called by muse, mutect2, varscan2
- TANC1 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs534711706, COSV55100228; called by muse, mutect2, varscan2
- TBC1D16 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749431309, COSV100188270, COSV60481068; called by muse, mutect2, varscan2
- TBC1D4 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.312); catalogued as rs1036748227, COSV100884710; called by muse, mutect2, varscan2
- TCF21 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52819841; called by muse, mutect2, varscan2
- THBS2 | c.2249C>A p.T750N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as rs1340855303, COSV100827982; called by muse, mutect2, varscan2
- THSD1 | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99318988; called by muse, mutect2, varscan2
- TNFSF4 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV99919444; called by muse, mutect2, varscan2
- TNR | c.3520G>T p.G1174W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99689559, COSV99690585; called by muse, mutect2, varscan2
- TOGARAM1 | c.4623T>A p.D1541E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.612); catalogued as COSV100818177; called by muse, varscan2
- TRDN | c.1031C>G p.A344G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV100522820; called by muse, mutect2, varscan2
- TRIM35 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs772068039, COSV100542797; called by muse, mutect2, varscan2
- TRPC4 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 45/79 reads (57%) | catalogued as COSV100157393; called by muse, mutect2, varscan2
- TTN | c.50740G>A p.A16914T (on ENST00000591111; = p.A9490T on NM_003319.4) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | PolyPhen probably damaging (0.998); catalogued as COSV100621708; called by muse, mutect2, varscan2
- TTN | c.25788C>A p.C8596* (on ENST00000591111; = p.C7669* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100621709; called by muse, mutect2, varscan2
- TTN | c.21398T>A p.V7133E (on ENST00000591111; = p.V6206E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/157 reads (45%) | PolyPhen probably damaging (0.971); catalogued as COSV100621710; called by muse, mutect2, varscan2
- UBR5 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99641623; called by muse, mutect2, varscan2
- UCK2 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100903017; called by muse, mutect2, varscan2
- UGT2B11 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV101485270; called by muse, mutect2, varscan2
- USH2A | c.10910C>T p.T3637I | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100238234; called by muse, mutect2, varscan2
- VPS33B | c.1245C>A p.Y415* | Nonsense Mutation (SNP) | VAF 80/148 reads (54%) | catalogued as COSV100325679; called by muse, mutect2, varscan2
- VRK2 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100418149; called by muse, mutect2, varscan2
- VSIG1 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 83/100 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1215732559, COSV99480405; called by muse, mutect2, varscan2
- WDR36 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs562223310, COSV101550950, COSV72605185; called by muse, mutect2, varscan2
- WDR62 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99543954; called by muse, mutect2, varscan2
- WNT2 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99626251; called by muse, mutect2, varscan2
- WWC1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.528); catalogued as rs750795143, COSV99515506; called by muse, mutect2, varscan2
- ZBTB11 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV100465663; called by muse, mutect2, varscan2
- ZC3H18 | c.2590G>C p.G864R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56323677, COSV99964289; called by muse, mutect2, varscan2
- ZDHHC3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs867335339, COSV99943464; called by muse, mutect2, varscan2
- ZFP82 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101088873, COSV101089213; called by muse, mutect2, varscan2
- ZFYVE27 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100519355; called by muse, mutect2, varscan2
- ZIC1 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV51557295; called by muse, mutect2, varscan2
- ZNF280B | c.530C>G p.T177S | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV100840382; called by muse, mutect2, varscan2
- ZNF518A | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV100283615, COSV100283689; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV58674573; called by muse, mutect2, varscan2
- ZNF608 | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as COSV100102118; called by muse, mutect2, varscan2
- ZNF629 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99354920; called by muse, mutect2, varscan2
- ZNF668 | c.1730G>T p.C577F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100336776; called by muse, mutect2, varscan2
- ZNF705A | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs766157387, COSV100828337, COSV100828338; called by muse, mutect2, varscan2
- ZNF750 | c.459_460insA p.E154Rfs*68 | Frame Shift Ins (INS) | VAF 27/50 reads (54%) | catalogued as COSV99489860; called by mutect2, pindel, varscan2
- ZNF829 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV101199688; called by muse, mutect2, varscan2
- ADAMTS19 | c.2453C>A p.A818D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by mutect2, varscan2
- ADAMTS19 | c.2454_2455insA p.G819Rfs*15 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- AGRN | c.345_347delinsTC p.F116Lfs*2 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | called by pindel, varscan2*
- CD163L1 | c.769_788del p.S257Afs*6 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- DACH2 | c.1043dup p.N348Kfs*103 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- FAT1 | c.5064_5065dup p.V1689Gfs*14 | Frame Shift Ins (INS) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- IGHA1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.172); called by muse, mutect2
- IGKV1D-43 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- LCOR | c.1133_1156del p.R378_E385del | In Frame Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- RBM27 | c.2536dup p.S846Ffs*34 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel
- RIMBP3 | c.3122A>T p.Y1041F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC27A6 | c.1003del p.A335Qfs*15 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- TNFRSF18 | c.626_639del p.P209Rfs*? | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- TRAV8-3 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 44/66 reads (67%) | called by muse, mutect2, varscan2
- ABCB11 | c.3951A>G p.G1317= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99792602; called by muse, mutect2, varscan2
- ABCC1 | c.2256C>T p.I752= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100579988; called by muse, mutect2, varscan2
- ADAM8 | c.1347G>A p.A449= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs373848180, COSV69864605; called by mutect2, varscan2
- ARHGAP45 | c.1800T>A p.T600= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100490935; called by muse, mutect2, varscan2
- BCAR1 | c.66C>T p.L22= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99366964; called by muse, mutect2, varscan2
- C1orf94 | c.1356C>T p.T452= (on ENST00000488417 / NM_001134734.2; = p.T262= on NM_032884.5) | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as COSV100975099; called by muse, mutect2, varscan2
- CACNA2D1 | c.3252C>A p.I1084= (on ENST00000356253 / NM_001366867.1; = p.I1072= on NM_000722.4) | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV100666959, COSV62388760; called by muse, mutect2, varscan2
- CD81 | c.105C>T p.L35= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs1458038102, COSV99719238; called by muse, mutect2, varscan2
- CDCA4 | c.393A>T p.P131= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100288243; called by muse, mutect2, varscan2
- CEP85L | c.492C>G p.A164= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100821317; called by muse, mutect2, varscan2
- CHEK1 | c.1398G>C p.V466= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99629790; called by muse, mutect2, varscan2
- CLMP | c.861C>G p.P287= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs746631557, COSV101507421; called by muse, mutect2, varscan2
- CNTNAP2 | c.2811C>A p.I937= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100668692; called by muse, mutect2, varscan2
- CRYBG3 | c.6723G>T p.L2241= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99477246; called by muse, mutect2, varscan2
- CSKMT | c.453G>A p.V151= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100649193; called by muse, mutect2, varscan2
- DACT1 | c.2337C>T p.S779= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs575793506, COSV100241854; called by muse, mutect2, varscan2
- DENND5A | c.2367G>A p.E789= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100065000; called by muse, mutect2, varscan2
- DNAH5 | c.2091G>A p.L697= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99451999; called by muse, mutect2, varscan2
- DPYSL4 | c.327C>T p.F109= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100633998; called by muse, mutect2, varscan2
- DZIP3 | c.309G>A p.L103= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs1298530621, COSV100847937; called by muse, mutect2, varscan2
- EPS15L1 | c.1002G>T p.A334= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV99933399; called by muse, mutect2, varscan2
- FAM98C | c.45C>T p.A15= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV53039285; called by muse, mutect2, varscan2
- GAD2 | c.1410T>C p.H470= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52169497, COSV99393685; called by muse, mutect2, varscan2
- GALNT2 | c.300C>G p.A100= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV100795840; called by muse, mutect2, varscan2
- GDF10 | c.987G>A p.R329= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- GPR158 | c.27C>T p.L9= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100894014; called by muse, mutect2, varscan2
- GRK3 | c.249G>A p.V83= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100151790; called by muse, mutect2, varscan2
- H1-6 | c.174A>T p.R58= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs533573752, COSV100619604; called by muse, mutect2, varscan2
- H2AC11 | c.186G>A p.E62= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs372313450; called by muse, mutect2, varscan2
- HSPA8 | c.936C>G p.G312= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99914509, COSV99914574; called by muse, mutect2, varscan2
- IGKV1D-43 | c.351T>A p.P117= | Silent (SNP) | VAF 42/188 reads (22%) | called by muse, varscan2
- IPMK | c.786G>A p.Q262= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100880392; called by muse, mutect2, varscan2
- ITGB8 | c.63A>T p.R21= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99751926; called by muse, mutect2, varscan2
- ITIH5 | c.12G>T p.L4= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99905288; called by muse, mutect2, varscan2
- KTI12 | c.9C>T p.L3= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV100860229; called by muse, mutect2, varscan2
- MFN1 | c.1755A>T p.V585= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV99764588; called by muse, mutect2, varscan2
- MLIP | c.741A>T p.P247= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99229923; called by muse, mutect2, varscan2
- MPRIP | c.2475G>A p.E825= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100505991; called by muse, mutect2, varscan2
- MUC16 | c.35964C>T p.A11988= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV101200532; called by muse, mutect2, varscan2
- MUC5AC | c.1698G>A p.Q566= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100650644; called by muse, mutect2
- MYH4 | c.2355A>G p.L785= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99701791; called by muse, mutect2, varscan2
- MYLK3 | c.768G>A p.E256= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV67364896; called by muse, mutect2, varscan2
- NCKAP5 | c.552G>A p.L184= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV58453130; called by muse, mutect2, varscan2
- NPAP1 | c.1749A>G p.P583= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100275740; called by muse, mutect2, varscan2
- NPAS3 | c.1872C>A p.G624= (on ENST00000356141 / NM_001164749.2; = p.G592= on NM_022123.3) | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as rs1445367648, COSV100640424; called by muse, mutect2, varscan2
- NTRK3 | c.2382C>T p.V794= (on ENST00000360948 / NM_001012338.2; = p.V780= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100713325; called by muse, mutect2
- OCA2 | c.2385G>C p.G795= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV62352661; called by muse, mutect2, varscan2
- OR5D14 | c.96G>A p.V32= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100162508; called by muse, mutect2, varscan2
- OR6K2 | c.870C>A p.I290= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100656835; called by muse, mutect2, varscan2
- OR8B3 | c.180C>T p.Y60= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs1258879613, COSV100660425; called by muse, mutect2, varscan2
- OR8H2 | c.438T>G p.T146= | Silent (SNP) | VAF 65/166 reads (39%) | catalogued as COSV100542408; called by muse, mutect2, varscan2
- PAM | c.2121G>T p.R707= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99173629; called by muse, mutect2, varscan2
- PCDHGA1 | c.1950C>A p.G650= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100966025; called by muse, mutect2, varscan2
- PCDHGA6 | c.1893C>G p.A631= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV54046294, COSV99542636; called by muse, mutect2, varscan2
- PCDHGA7 | c.1548G>C p.A516= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99542638; called by muse, mutect2, varscan2
- PCDHGB3 | c.1845G>T p.G615= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99542633; called by muse, mutect2, varscan2
- PIK3R4 | c.3396G>A p.A1132= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs764380710, COSV100768529; called by muse, mutect2, varscan2
- PNISR | c.1197G>A p.E399= | Silent (SNP) | VAF 66/211 reads (31%) | catalogued as COSV100984394; called by muse, mutect2, varscan2
- POLQ | c.409C>A p.R137= | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as COSV51752509, COSV99952579; called by muse, mutect2, varscan2
- PRR23B | c.711G>T p.P237= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100272157, COSV61494082; called by muse, mutect2, varscan2
- PZP | c.2190A>G p.S730= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV99738717; called by muse, mutect2, varscan2
- RHCG | c.1206G>A p.L402= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV99174164; called by muse, mutect2, varscan2
- RYR2 | c.813A>T p.A271= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100772011; called by muse, mutect2, varscan2
- S100A7A | c.120C>T p.F40= | Silent (SNP) | VAF 69/150 reads (46%) | catalogued as COSV61330802, COSV61331142; called by muse, mutect2, varscan2
- SEMA5B | c.3372G>T p.T1124= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99532575; called by muse, mutect2, varscan2
- SETX | c.1575C>T p.S525= | Silent (SNP) | VAF 107/145 reads (74%) | catalogued as COSV99810362; called by muse, mutect2, varscan2
- SKI | c.423G>C p.A141= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs767973122, COSV101049496; called by muse, varscan2
- SLC35F5 | c.579T>C p.R193= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99830132; called by muse, mutect2, varscan2
- SLC6A2 | c.60T>G p.G20= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1236577996, COSV99574252; called by muse, mutect2, varscan2
- SMR3A | c.237C>A p.S79= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV56949696, COSV56950252; called by muse, mutect2, varscan2
- SPOP | c.219C>G p.P73= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100753484; called by muse, mutect2, varscan2
- SPRY3 | c.52C>T p.L18= | Silent (SNP) | VAF 77/121 reads (64%) | catalogued as COSV100249445; called by muse, mutect2, varscan2
- TBXT | c.708C>T p.S236= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV51617134; called by muse, mutect2, varscan2
- TEC | c.861C>G p.T287= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as COSV100797952, COSV100797965; called by muse, mutect2, varscan2
- TFCP2L1 | c.897C>T p.P299= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs752230601, COSV99748201, COSV99748481; called by muse, mutect2, varscan2
- TNIK | c.2541G>A p.E847= | Silent (SNP) | VAF 155/774 reads (20%) | catalogued as COSV99458518; called by muse, mutect2, varscan2
- TOR1B | c.87C>T p.T29= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV99400262; called by muse, mutect2, varscan2
- TRAPPC12 | c.1701G>C p.A567= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs116179331, COSV100160765; called by muse, mutect2, varscan2
- TTN | c.6876A>G p.P2292= (on ENST00000591111; = p.P2246= on NM_003319.4) | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as COSV100621716; called by muse, mutect2, varscan2
- UIMC1 | c.732C>T p.L244= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV101022192; called by muse, mutect2, varscan2
- USH2A | c.8829G>T p.V2943= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100228002, COSV100238854, COSV100239689; called by muse, mutect2, varscan2
- VPS13C | c.9207C>T p.A3069= (on ENST00000644861 / NM_020821.3; = p.A3026= on NM_017684.5) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99829422; called by muse, mutect2, varscan2
- ZBTB6 | c.357C>T p.C119= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV101022037; called by muse, mutect2, varscan2
- ZFHX4 | c.7770C>T p.C2590= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs543313918, COSV50757417, COSV99265391; called by muse, mutect2, varscan2
- ZNF585B | c.2163T>C p.A721= | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as COSV100459562; called by muse, mutect2, varscan2
- ZNF608 | c.3222G>T p.L1074= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100102120; called by muse, mutect2, varscan2
- AC024940.1 | n.2266T>A | RNA (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- BMP1 | c.2107+1687C>T | Intron (SNP) | VAF 12/73 reads (16%) | catalogued as rs148038163; called by muse, mutect2, varscan2
- CHD8 | c.6772-238T>G | Intron (SNP) | VAF 36/66 reads (55%) | catalogued as COSV100765337; called by muse, mutect2, varscan2
- CSMD3 | c.178+59901G>T | Intron (SNP) | VAF 39/84 reads (46%) | catalogued as COSV99841246; called by muse, mutect2, varscan2
- DCHS2 | n.2163G>T | RNA (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100252531; called by muse, mutect2, varscan2
- IGLL3P | n.199T>C | RNA (SNP) | VAF 73/106 reads (69%) | called by muse, mutect2, varscan2
- SNORD115-13 | n.80C>A | RNA (SNP) | VAF 165/317 reads (52%) | catalogued as rs762091136; called by muse, mutect2, varscan2
- TTN | c.10361-5186C>T | Intron (SNP) | VAF 62/160 reads (39%) | catalogued as COSV100621712, COSV100635389; called by muse, mutect2, varscan2
- TTN | c.10361-5547A>G | Intron (SNP) | VAF 36/133 reads (27%) | catalogued as COSV100621714; called by muse, mutect2, varscan2
- TTN | c.10360+4654C>T | Intron (SNP) | VAF 70/207 reads (34%) | catalogued as rs1560995999, COSV100621715; called by muse, mutect2, varscan2
- USH1C | c.1284+6944T>A | Intron (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99140731; called by muse, mutect2
- ZNF467 | chr7:149776994 G>T | 5'Flank (SNP) | VAF 14/78 reads (18%) | catalogued as rs529229055; called by muse, mutect2, varscan2
